Somatic mutation profile of tumor specimen TCGA-YU-A94D-01A (aliquot TCGA-YU-A94D-01A-11D-A435-10) from TCGA case TCGA-YU-A94D, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, malignant, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 28.5 years (10,427 days).
Specimen TCGA-YU-A94D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4637a05f-48a0-428e-916a-fed08f784d73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-A94D-10A (Blood Derived Normal), aliquot TCGA-YU-A94D-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a43a59e1-3fab-4b3b-b9ba-0fcf407d21e8

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPSF1 | c.3520G>A p.A1174T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as rs782673364; called by muse, mutect2, varscan2
- DGKI | c.3101G>T p.R1034I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as COSV55955945; called by muse, mutect2
- EMC3 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55278043; called by muse, mutect2, varscan2
- MAGEB10 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV63311386; called by muse, mutect2, varscan2
- NTHL1 | c.469C>T p.R157W (on ENST00000219066; = p.R149W on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs376048896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPEF1 | c.1875C>A p.S625R | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.718); catalogued as COSV62996907; called by muse, mutect2, varscan2
- VSIG8 | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs777306859; called by muse, mutect2, varscan2
- CEP128 | c.1084_1116del p.E362_L372del | In Frame Del (DEL) | VAF 72/236 reads (31%) | called by mutect2, pindel, varscan2
- COL4A5 | c.4244G>A p.G1415D | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIS3 | c.2600_2601del p.Y867Wfs*9 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- EID3 | c.983T>A p.I328N | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOCAD | c.1526T>C p.I509T | Missense Mutation (SNP) | VAF 175/454 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- HEPH | c.3049T>A p.Y1017N (on ENST00000343002; = p.Y750N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MED14 | c.1065C>A p.H355Q | Missense Mutation (SNP) | VAF 154/378 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, varscan2
- SMS | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SOCS4 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- TMEM182 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | called by muse, mutect2, varscan2
- ZNF682 | c.365_366del p.E122Vfs*2 | Frame Shift Del (DEL) | VAF 46/114 reads (40%) | called by mutect2, pindel, varscan2
- KIF14 | c.4215A>G p.K1405= | Silent (SNP) | VAF 66/190 reads (35%) | called by muse, mutect2, varscan2
- TFAP2D | c.1200A>C p.T400= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs375378399; called by muse, mutect2, varscan2
- TXK | c.144G>A p.P48= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs200958317; called by muse, mutect2, varscan2
- WHRN | c.528A>G p.L176= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs1178301243; called by muse, mutect2, varscan2
